Somatic mutation profile of tumor specimen 0DSP28 from CCDI case PBCIKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.1 years (4,059 days).
Specimen 0DSP28: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbf485d0-14d5-4293-aa06-00b380ac7f42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a79ec494-c454-47e0-8462-16a4bbab0b19

The open-access MAF lists 535 somatic variants for this specimen: 336 protein-altering or splice-affecting, 115 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 115, Intron 51, 3'UTR 22, Nonsense Mutation 22, Frame Shift Del 17, 5'UTR 9, In Frame Del 8, Frame Shift Ins 6, Splice Site 5, Splice Region 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL9A1 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 359/951 reads (38%) | catalogued as rs121912931, CM063918; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 273/755 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MSH2 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 489/1285 reads (38%) | catalogued as rs63749932, CM970977, COSV51875657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.14209C>T p.R4737W | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193922867, CM023979; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 466/1088 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 248/641 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AASS | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 509/1237 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762873545, COSV62788607, COSV62790642; called by muse, mutect2, varscan2
- ABCA13 | c.11989G>A p.V3997M | Missense Mutation (SNP) | VAF 447/1115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767265037, COSV101447063; called by muse, mutect2, varscan2
- ABCA2 | c.322G>A p.G108S (on ENST00000614293; = p.G78S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 265/672 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1322969154; called by muse, varscan2
- ADAMTS10 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 179/432 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as rs144419462; called by muse, mutect2, varscan2
- ADAMTS12 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 337/901 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61754760; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3419G>C p.G1140A | Missense Mutation (SNP) | VAF 375/927 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV65891494; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 220/521 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs759359114, COSV58448939; called by muse, mutect2, varscan2
- AGPAT2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 211/507 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs767338891, COSV58246848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AJM1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1429413360, COSV99915856; called by muse, mutect2, varscan2
- AKAP12 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 345/887 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1374258763; called by muse, mutect2, varscan2
- ALDH9A1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 460/1093 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370269292; called by muse, mutect2, varscan2
- ALK | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766551269, COSV66585330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPG | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779337; called by muse, mutect2, varscan2
- ALPK2 | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 392/1031 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780229836, COSV64493464, COSV64495035; called by muse, mutect2
- ALPP | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 360/1821 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140213522; called by muse, mutect2, varscan2
- ANKDD1A | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 116/147 reads (79%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs367982055; called by muse, mutect2, varscan2
- ANKMY1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 344/818 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547716704, COSV56031488; called by muse, mutect2, varscan2
- ANKRD35 | c.17_19del p.S6del | In Frame Del (DEL) | VAF 331/825 reads (40%) | catalogued as rs781784699; called by mutect2, pindel, varscan2
- ANO1 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 363/881 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1248563046; called by muse, mutect2, varscan2
- AP1M2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 352/791 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746080407, COSV51566567; called by muse, mutect2, varscan2
- APBA1 | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 414/979 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1256767961; called by muse, mutect2, varscan2
- AQP7 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 198/470 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs371783551; called by muse, mutect2, varscan2
- ARHGAP23 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 233/625 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs945381469; called by muse, mutect2, varscan2
- ARHGAP9 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 321/792 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs147287939; called by muse, mutect2, varscan2
- ASB13 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 323/774 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.225); catalogued as rs761943608, COSV63090521; called by muse, mutect2, varscan2
- ATN1 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 339/818 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781906555, COSV57546899; called by muse, mutect2, varscan2
- BAG6 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 313/655 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369200113; called by muse, mutect2, varscan2
- BCAR1 | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 153/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs974867909, COSV50793864; called by muse, mutect2, varscan2
- BECN2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 157/346 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs774258195; called by muse, mutect2, varscan2
- BOD1L2 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 174/412 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs777409039; called by muse, mutect2, varscan2
- BTBD6 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs145825360; called by muse, mutect2, varscan2
- C17orf99 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 36/830 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.152); catalogued as rs955654857; called by muse, mutect2
- C4orf47 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 454/1130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572578751; called by muse, mutect2, varscan2
- C5 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 434/1102 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768081493; called by muse, mutect2, varscan2
- CA6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 421/917 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs533616544, COSV66262258, COSV66263535; called by muse, mutect2, varscan2
- CACNA1E | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 471/1125 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1294061346, COSV100701959; called by muse, mutect2, varscan2
- CACNA1H | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 320/823 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs199669141; called by muse, mutect2, varscan2
- CACNA2D2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 293/703 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs769033285, COSV56570278; called by muse, mutect2, varscan2
- CARMIL3 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 444/1006 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs767755727; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 384/868 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs575224033; called by muse, mutect2, varscan2
- CHORDC1 | c.521_523del p.E174del | In Frame Del (DEL) | VAF 146/468 reads (31%) | catalogued as rs754173552; called by pindel, varscan2
- CIT | c.3220_3221del p.S1074Qfs*25 | Frame Shift Del (DEL) | VAF 212/574 reads (37%) | catalogued as rs1332909856; called by pindel, varscan2
- CLASP2 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 49/1876 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1460863047; called by muse, mutect2
- CLTCL1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 304/799 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs781855982, COSV54232961; called by muse, mutect2, varscan2
- CMTR1 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 174/406 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1471265719, COSV100990895, COSV65090264; called by muse, mutect2, varscan2
- CNGB1 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 387/955 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376051016, COSV51902102; called by muse, mutect2, varscan2
- CNTN3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 445/1119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs569008734, COSV55162972; called by muse, mutect2, varscan2
- CNTN6 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 441/990 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752027829, COSV63161676; called by muse, mutect2, varscan2
- COL5A1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 362/841 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs140943202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ10A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 382/914 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs539883215; called by muse, mutect2, varscan2
- CPSF3 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 303/720 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs763418256; called by muse, mutect2, varscan2
- CSTF2T | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 547/1339 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58657289; called by muse, mutect2, varscan2
- CUBN | c.6802G>A p.D2268N | Missense Mutation (SNP) | VAF 728/1684 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758830155; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 353/835 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CYP2B6 | c.823-5C>T | Splice Region (SNP) | VAF 169/454 reads (37%) | catalogued as rs374642809; called by muse, mutect2, varscan2
- CYP51A1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 274/676 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs528934873, COSV50153617; called by muse, varscan2
- DHDH | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 193/507 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs752639038, COSV55483874; called by muse, mutect2
- DHX16 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 310/827 reads (37%) | catalogued as rs755284626, COSV100905156, COSV64565639; called by muse, mutect2, varscan2
- DNAI3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 446/1114 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.487); catalogued as rs753211625, COSV54004277; called by muse, mutect2, varscan2
- DOCK3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 392/983 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs942444952; called by muse, mutect2, varscan2
- DOCK6 | c.5956C>T p.R1986W | Missense Mutation (SNP) | VAF 323/759 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs36059048, COSV53921500; called by muse, mutect2, varscan2
- DPP9 | c.1148C>T p.P383L (on ENST00000598800; = p.P412L on NM_139159.5) | Missense Mutation (SNP) | VAF 297/671 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as rs760835832, COSV53593143; called by muse, mutect2, varscan2
- DSCAML1 | c.3709G>A p.V1237I (on ENST00000321322; = p.V1177I on NM_020693.4) | Missense Mutation (SNP) | VAF 228/551 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs544850403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 590/1517 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177698609; called by muse, mutect2, varscan2
- DYNC2H1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 541/1303 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs869312924, CM1515005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 296/729 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs757615854; called by muse, mutect2, varscan2
- E2F3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 447/1154 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs188266138, COSV60897232; called by muse, mutect2, varscan2
- ECHS1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 288/371 reads (78%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); catalogued as rs555404939, COSV63906648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECPAS | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 321/833 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs756031737, COSV52190987; called by muse, mutect2, varscan2
- ECSIT | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 272/614 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs763948307; called by muse, mutect2, varscan2
- EEF2K | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 302/661 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747658944, COSV53779724; called by muse, mutect2, varscan2
- EIF4E1B | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 222/470 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs1349208093, COSV53779194; called by muse, mutect2, varscan2
- EML6 | c.5024dup p.N1675Kfs*5 | Frame Shift Ins (INS) | VAF 444/1119 reads (40%) | catalogued as rs1008972663; called by mutect2, varscan2
- EPB41L1 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 213/526 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs756602980, COSV99151337; called by muse, mutect2, varscan2
- EPPK1 | c.6794C>T p.A2265V | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV73260969; called by muse, mutect2, varscan2
- F2RL3 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs369129094, COSV50186355; called by muse, mutect2, varscan2
- FAM160A2 | c.2432C>T p.A811V (on ENST00000449352 / NM_001098794.2; = p.A825V on NM_032127.4) | Missense Mutation (SNP) | VAF 401/1028 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1467164737; called by muse, mutect2, varscan2
- FAM171A1 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 162/1309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355728906, COSV100968296; called by muse, mutect2, varscan2
- FAM199X | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 22/838 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs782753759, COSV55433224, COSV55433596; called by muse, mutect2
- FAT4 | c.7312G>T p.V2438F | Missense Mutation (SNP) | VAF 436/1077 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs376545643; called by muse, mutect2, varscan2
- FILIP1 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 437/1084 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.592); catalogued as COSV52726552; called by muse, mutect2, varscan2
- FLG2 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 455/1056 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs961111246; called by muse, mutect2, varscan2
- FMOD | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 281/625 reads (45%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.431); catalogued as rs772265764, COSV61609968; called by muse, mutect2, varscan2
- FRAS1 | c.7066C>T p.R2356C | Missense Mutation (SNP) | VAF 455/1119 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1229209820; called by muse, mutect2, varscan2
- FRMD3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 373/885 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs777625741, COSV58461057; called by muse, mutect2, varscan2
- GALNT18 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 433/1020 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs759039128; called by muse, mutect2, varscan2
- GCOM1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 502/663 reads (76%) | catalogued as rs750168470, COSV51091500; called by muse, mutect2, varscan2
- GGA1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 295/627 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs199622924; called by muse, mutect2, varscan2
- GNB1L | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 146/344 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as rs371832244; called by muse, mutect2, varscan2
- GON4L | c.5774G>A p.R1925Q | Missense Mutation (SNP) | VAF 263/608 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs536850613; called by muse, mutect2, varscan2
- GPC1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 353/738 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754216019; called by muse, mutect2, varscan2
- GSG1L | c.746G>A p.R249Q (on ENST00000447459 / NM_001109763.2; = p.R94Q on NM_144675.2) | Missense Mutation (SNP) | VAF 418/988 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as rs767489098, COSV66580934; called by muse, varscan2
- GTF3C1 | c.3649C>T p.R1217W | Missense Mutation (SNP) | VAF 371/882 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758894305; called by muse, mutect2, varscan2
- HDAC3 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 296/758 reads (39%) | catalogued as rs777247903, COSV100539474, COSV59495276; called by muse, mutect2, varscan2
- HMBOX1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 594/1474 reads (40%) | catalogued as COSV104382083; called by muse, mutect2, varscan2
- HOMER3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 33/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1042266047; called by muse, mutect2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 189/478 reads (40%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- IGFBP1 | c.268del p.E90Sfs*40 | Frame Shift Del (DEL) | VAF 111/327 reads (34%) | catalogued as rs747136225; called by mutect2, pindel, varscan2
- IGFBP7 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 258/702 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs372546968; called by muse, mutect2, varscan2
- IKZF1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 509/1261 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58781896; called by muse, mutect2, varscan2
- INKA1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760737503, COSV58525719; called by muse, mutect2, varscan2
- IQCA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 389/959 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771403726, COSV54494846; called by muse, mutect2, varscan2
- IRS1 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 311/826 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775603579, COSV59338104; called by muse, mutect2, varscan2
- ITGA3 | c.3046-5C>T | Splice Region (SNP) | VAF 447/1009 reads (44%) | catalogued as rs374371717; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGA6 | c.1850G>A p.R617H (on ENST00000442250; = p.R578H on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 182/930 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs533796307; called by muse, mutect2, varscan2
- ITGB6 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 331/859 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747415493; called by muse, mutect2, varscan2
- KATNB1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 331/891 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.273); catalogued as rs782335200; called by muse, mutect2, varscan2
- KATNIP | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 312/784 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs764586233, COSV55181838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA7 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 165/394 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773591235; called by muse, mutect2, varscan2
- KCNIP3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 226/620 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs545775980; called by muse, mutect2, varscan2
- KCNJ10 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 374/946 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs779913708; called by muse, mutect2, varscan2
- KCNK5 | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 201/489 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100851826; called by muse, mutect2, varscan2
- KCNMA1 | c.3209C>T p.P1070L (on ENST00000286628 / NM_001161352.2; = p.P1012L on NM_002247.4) | Missense Mutation (SNP) | VAF 520/1210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1364516204, COSV99694421; called by muse, mutect2, varscan2
- KCNMA1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 388/949 reads (41%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.683); catalogued as rs770230666, COSV54279448; called by muse, mutect2, varscan2
- KCNQ2 | c.2555C>T p.P852L (on ENST00000359125 / NM_172107.4; = p.P824L on NM_004518.6) | Missense Mutation (SNP) | VAF 255/616 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.69); catalogued as rs745508762, COSV100609924, COSV100610594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCP | c.4375G>A p.G1459S (on ENST00000620378; = p.G1583S on NM_001366122.1) | Missense Mutation (SNP) | VAF 206/433 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs749774628; called by muse, mutect2, varscan2
- KDM4E | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 480/1216 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs193213319; called by muse, mutect2, varscan2
- LEXM | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 314/743 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.259); catalogued as rs139677684; called by muse, mutect2, varscan2
- LIPA | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 260/520 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449945329, COSV51081095; called by muse, mutect2, varscan2
- LRIF1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 611/1441 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773742909; called by muse, mutect2, varscan2
- LRP2 | c.7499G>A p.R2500H | Missense Mutation (SNP) | VAF 644/1431 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs199910334; called by muse, mutect2, varscan2
- LRRC37A3 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760812476, COSV100141110; called by mutect2, varscan2
- LRRN1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 727/1712 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs755846334, COSV60012217; called by muse, mutect2, varscan2
- LTBP2 | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 391/983 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs141033298; called by muse, mutect2, varscan2
- LURAP1 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 294/701 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776263232; called by muse, mutect2, varscan2
- MADD | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 467/1054 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs751325656; called by muse, mutect2, varscan2
- MARCHF1 | c.741dup p.L248Tfs*8 (on ENST00000274056; = p.L231Tfs*8 on NM_017923.4) | Frame Shift Ins (INS) | VAF 136/826 reads (16%) | catalogued as rs1343553266; called by mutect2, pindel, varscan2
- MARK2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 498/1148 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs973521004, COSV59288594, COSV59289098; called by muse, mutect2, varscan2
- MEGF8 | c.4528C>T p.R1510C (on ENST00000251268 / NM_001271938.2; = p.R1443C on NM_001410.3) | Missense Mutation (SNP) | VAF 270/698 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774663979; called by muse, mutect2, varscan2
- MFSD10 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 298/768 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs551811310, COSV53274463; called by muse, mutect2, varscan2
- MIB2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 186/435 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764749915; called by muse, mutect2, varscan2
- MRPS18B | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 707/1724 reads (41%) | catalogued as rs1039375257; called by muse, mutect2, varscan2
- MSLN | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748453506; called by muse, mutect2, varscan2
- MUTYH | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 238/586 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs587780084, COSV58343979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.5977C>T p.R1993W | Missense Mutation (SNP) | VAF 180/489 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759663463; called by muse, mutect2, varscan2
- MYO7A | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 334/701 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782172320; called by muse, mutect2, varscan2
- MYO9B | c.6338C>T p.T2113M | Missense Mutation (SNP) | VAF 164/381 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs751896302; called by muse, mutect2, varscan2
- NACC1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 191/462 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs773484210; called by muse, mutect2, varscan2
- NADK2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 405/1138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201353448; called by muse, mutect2, varscan2
- NCKAP1L | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 173/990 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs373626744; called by muse, mutect2, varscan2
- NCOR1 | c.6299G>A p.R2100H | Missense Mutation (SNP) | VAF 639/1487 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs763361060, COSV51969264; called by muse, varscan2
- NCOR2 | c.3178dup p.R1060Pfs*2 | Frame Shift Ins (INS) | VAF 208/629 reads (33%) | catalogued as rs749518211; called by mutect2, varscan2
- NDOR1 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 259/642 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs201890424, COSV100789071; called by muse, mutect2, varscan2
- NDUFA8 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 390/1069 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs755337755, COSV65653613; called by muse, mutect2, varscan2
- NELFA | c.1373C>T p.T458M (on ENST00000542778; = p.T447M on NM_005663.5) | Missense Mutation (SNP) | VAF 162/445 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs756656144, COSV56392803; called by muse, mutect2, varscan2
- NFATC2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 484/1193 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769968405; called by muse, mutect2, varscan2
- NFIC | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 225/550 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs548851795; called by muse, mutect2, varscan2
- NPHP3 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 499/1240 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139548649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C1B | c.1200C>T p.Y400= (on ENST00000359846 / NM_001199086.2; = p.Y340= on NM_033253.4) | Splice Region (SNP) | VAF 582/1355 reads (43%) | catalogued as rs148193506; called by muse, mutect2, varscan2
- OPTN | c.626+1G>A p.X209_splice | Splice Site (SNP) | VAF 438/1059 reads (41%) | catalogued as rs756957223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR51A4 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 117/1133 reads (10%) | catalogued as rs773692308; called by muse, mutect2, varscan2
- OR7C1 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 298/718 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs141077779; called by muse, mutect2, varscan2
- OSBPL5 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 308/760 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as rs370324105, COSV55139930; called by muse, mutect2
- P3H1 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 258/701 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs538936362, COSV52535633; called by muse, mutect2, varscan2
- PABPC4 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 552/1348 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs774189086; called by muse, mutect2, varscan2
- PAPOLA | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 426/1021 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53479938; called by muse, mutect2, varscan2
- PC | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 306/722 reads (42%) | catalogued as CM134801, COSV63082362; called by muse, mutect2, varscan2
- PCDH9 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 575/1383 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs375314712, COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PCDHB13 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); catalogued as rs782573875; called by muse, mutect2, varscan2
- PCSK7 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 297/725 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1206125745; called by muse, mutect2, varscan2
- PDGFRA | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 539/1276 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV57269361; called by muse, varscan2
- PDGFRB | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 334/850 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as rs377445092, COSV55803933; called by muse, mutect2, varscan2
- PGBD2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 354/918 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs199974890; called by muse, varscan2
- PHIP | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 663/1602 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV51507676; called by muse, mutect2, varscan2
- PHYKPL | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 253/693 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57425833; called by muse, mutect2, varscan2
- PIEZO1 | c.2026A>G p.S676G | Missense Mutation (SNP) | VAF 217/524 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1386090024; called by muse, mutect2, varscan2
- PIK3AP1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 421/1014 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100225415, COSV100225817; called by muse, mutect2, varscan2
- PIK3C2B | c.4121G>A p.R1374H | Missense Mutation (SNP) | VAF 539/1359 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); catalogued as rs776940848, COSV65811820; called by muse, mutect2, varscan2
- PIM1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 460/1147 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs1244024334, COSV100998561; called by muse, varscan2
- PIMREG | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 269/686 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as rs377526630; called by muse, mutect2, varscan2
- PLEC | c.4549G>A p.A1517T (on ENST00000322810 / NM_201380.4; = p.A1407T on NM_000445.5) | Missense Mutation (SNP) | VAF 188/459 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs960723686; called by muse, mutect2, varscan2
- PLEKHM1 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 285/690 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759299269; called by muse, mutect2, varscan2
- PLEKHM3 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 472/1115 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1332782146, COSV66817540; called by muse, mutect2, varscan2
- PLXNA2 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 290/754 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765330302; called by muse, mutect2, varscan2
- PLXNB1 | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 222/506 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs774548685; called by muse, mutect2, varscan2
- PLXNB3 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 501/561 reads (89%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs782058864, COSV62796856; called by muse, mutect2, varscan2
- POU6F2 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 49/1093 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1318441973; called by muse, mutect2
- PRM1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 242/546 reads (44%) | PolyPhen probably damaging (0.928); catalogued as rs374230515; called by muse, mutect2, varscan2
- PRPF3 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 294/758 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs910066987; called by muse, mutect2, varscan2
- PRR32 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 748/852 reads (88%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs751085901; called by muse, mutect2, varscan2
- PTPN3 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 476/1151 reads (41%) | catalogued as rs781102733, COSV99355278; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 343/715 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1374925013; called by muse, mutect2, varscan2
- RAD54B | c.2504_2506del p.E835del | In Frame Del (DEL) | VAF 332/830 reads (40%) | catalogued as rs781464824; called by pindel, varscan2
- RBBP5 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 444/1158 reads (38%) | catalogued as rs749617380; called by muse, varscan2
- RCOR2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 361/870 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1420149842, COSV56850137; called by muse, mutect2, varscan2
- RGS3 | c.2048C>T p.T683M (on ENST00000350696 / NM_001282923.2; = p.T402M on NM_130795.4) | Missense Mutation (SNP) | VAF 498/1298 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.361); catalogued as rs199781930; called by muse, mutect2, varscan2
- RNF128 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1383619529, COSV55249237; called by muse, mutect2, varscan2
- RNF213 | c.5449G>A p.V1817M | Missense Mutation (SNP) | VAF 221/610 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs748288455; called by muse, mutect2, varscan2
- RNF26 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 142/292 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs372385504, COSV60990284; called by muse, mutect2, varscan2
- ROMO1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 517/1199 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs749056787, COSV53617875; called by muse, mutect2, varscan2
- RTL1 | c.3373C>T p.R1125* | Nonsense Mutation (SNP) | VAF 156/424 reads (37%) | catalogued as rs1288248204, COSV101128508; called by muse, mutect2, varscan2
- SCAF4 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 579/1343 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99740734; called by muse, mutect2, varscan2
- SCAMP1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 433/1176 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs750834214; called by muse, mutect2, varscan2
- SCARF2 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 154/364 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs751535844, COSV56731428; called by muse, mutect2, varscan2
- SCN10A | c.4766C>T p.A1589V | Missense Mutation (SNP) | VAF 437/1017 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs753004431, COSV71860872; called by muse, mutect2, varscan2
- SETD1B | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen probably damaging (0.923); catalogued as rs1333865285; called by muse, mutect2, varscan2
- SETD2 | c.6362G>A p.R2121H | Missense Mutation (SNP) | VAF 522/1296 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57441748; called by muse, mutect2, varscan2
- SGSM1 | c.3052G>A p.A1018T (on ENST00000400359 / NM_001039948.4; = p.A957T on NM_133454.3) | Missense Mutation (SNP) | VAF 404/1081 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762566387; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 224/612 reads (37%) | catalogued as rs777796332; called by mutect2, varscan2
- SHANK1 | c.6200del p.G2067Efs*66 | Frame Shift Del (DEL) | VAF 124/345 reads (36%) | catalogued as COSV53248574, COSV53250671; called by mutect2, pindel, varscan2
- SHFL | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 175/446 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1385952821; called by muse, mutect2, varscan2
- SHROOM3 | c.3461C>T p.T1154M | Missense Mutation (SNP) | VAF 231/547 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV104406578; called by muse, mutect2, varscan2
- SLC27A1 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs764202120, COSV99393027; called by muse, mutect2, varscan2
- SLC4A3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 190/490 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.973); catalogued as rs776495005, COSV56097525; called by muse, mutect2, varscan2
- SLC6A12 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 212/529 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781320561, COSV62885713; called by muse, mutect2, varscan2
- SLC8A3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 472/1097 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs369662157; called by muse, mutect2, varscan2
- SLC9A4 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 478/1160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs144537340, COSV54829571; called by muse, mutect2, varscan2
- SNRNP70 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 224/624 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99672430; called by muse, varscan2
- SOCS5 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 644/1551 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs773889273, COSV100125242; called by muse, mutect2, varscan2
- SON | c.3335G>A p.R1112Q | Missense Mutation (SNP) | VAF 681/1576 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1022299315; called by muse, mutect2, varscan2
- SORBS3 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 196/564 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs747756489; called by muse, mutect2, varscan2
- SPAG5 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 463/1104 reads (42%) | catalogued as rs756148727; called by muse, mutect2, varscan2
- SPANXN3 | c.71del p.N24Mfs*12 | Frame Shift Del (DEL) | VAF 410/478 reads (86%) | catalogued as rs781940283; called by mutect2, varscan2
- SPINDOC | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 230/525 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs779579398, COSV53692734; called by muse, mutect2, varscan2
- SPTA1 | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 460/1220 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs570759939; called by mutect2, varscan2
- SPTAN1 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 873/1967 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63989710; called by muse, mutect2, varscan2
- SPTBN1 | c.6476C>T p.T2159M | Missense Mutation (SNP) | VAF 477/1220 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs35357181; called by muse, mutect2, varscan2
- SRCAP | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 540/1350 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52679933; called by muse, mutect2, varscan2
- STAG2 | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 124/801 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54359363; called by muse, mutect2, varscan2
- STAM | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 304/731 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.162); catalogued as rs375357156; called by muse, mutect2, varscan2
- STRC | c.4730G>A p.R1577Q | Missense Mutation (SNP) | VAF 282/536 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs757346220; called by muse, mutect2, varscan2
- TAOK3 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 315/836 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781159188, COSV66824720; called by muse, mutect2, varscan2
- TBC1D13 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 307/696 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs868222595; called by muse, mutect2, varscan2
- TCHH | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 353/761 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs201786902; called by muse, mutect2, varscan2
- TET3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 461/1037 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs772068945, COSV59880303; called by muse, mutect2, varscan2
- TFRC | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 501/1231 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772641140, COSV100786409, COSV64053836; called by muse, mutect2, varscan2
- TLCD3A | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 525/1292 reads (41%) | catalogued as rs747021307; called by muse, mutect2, varscan2
- TLE4 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 502/1290 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs754468656; called by muse, mutect2, varscan2
- TMED3 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 267/616 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs756104785, COSV55302892; called by muse, mutect2, varscan2
- TMUB1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 292/638 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745493234; called by muse, mutect2, varscan2
- TNIP1 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 559/1331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759431804; called by muse, mutect2, varscan2
- TRAPPC10 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 311/748 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs149723115; called by mutect2, varscan2
- TRIM3 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 368/748 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs1244836762; called by muse, mutect2, varscan2
- TRPC4AP | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 372/904 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs187038762; called by mutect2, varscan2
- TRPV4 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 392/906 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758280554, COSV55681421; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TSHZ3 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 217/576 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs766398534; called by muse, mutect2, varscan2
- TTBK1 | c.3232C>T p.R1078W | Missense Mutation (SNP) | VAF 300/695 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs774148264; called by muse, mutect2, varscan2
- TUT1 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 217/522 reads (42%) | catalogued as rs928294458; called by muse, mutect2, varscan2
- UHRF1 | c.2303G>A p.R768H (on ENST00000612630 / NM_001290050.1; = p.R781H on NM_013282.4) | Missense Mutation (SNP) | VAF 194/564 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774702816; called by muse, mutect2, varscan2
- UPF1 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 280/722 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs759528312, COSV53195546; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 239/665 reads (36%) | catalogued as rs767420916; called by mutect2, varscan2
- USP24 | c.3449A>G p.H1150R | Missense Mutation (SNP) | VAF 637/1626 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.19); catalogued as rs1314040054; called by muse, mutect2, varscan2
- UTRN | c.9379C>T p.R3127* | Nonsense Mutation (SNP) | VAF 155/423 reads (37%) | catalogued as rs1221330316, COSV100837894; called by muse, mutect2, varscan2
- VPREB1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 70/706 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763074545, COSV56425836; called by muse, mutect2, varscan2
- VWA7 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 553/1359 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752870765; called by muse, mutect2, varscan2
- WDR20 | c.1013_1015del p.L338del | In Frame Del (DEL) | VAF 180/497 reads (36%) | catalogued as rs777848654; called by pindel, varscan2
- WDR59 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 327/793 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs376456550; called by muse, mutect2, varscan2
- WDR7 | c.3845C>T p.T1282M | Missense Mutation (SNP) | VAF 372/900 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs780898536; called by muse, mutect2, varscan2
- WNK2 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 235/574 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355562656, COSV52963582; called by muse, mutect2, varscan2
- XRN2 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 614/1540 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.885); catalogued as rs771948880, COSV101018032, COSV65870602; called by muse, varscan2
- YJU2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 192/458 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs762036683; called by muse, mutect2, varscan2
- ZAN | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 263/691 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.766); catalogued as rs752389582; called by muse, mutect2, varscan2
- ZBTB7C | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.179); catalogued as rs752620585; called by muse, mutect2, varscan2
- ZC3H11A | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 533/1274 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs571981678, COSV59750707; called by muse, mutect2, varscan2
- ZDHHC4 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 418/957 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs150919608, COSV60106615; called by muse, mutect2, varscan2
- ZMYM1 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 512/1297 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs190068364; called by muse, varscan2
- ZNF142 | c.4168C>T p.R1390W (on ENST00000411696 / NM_001379660.1; = p.R1190W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 218/452 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs760537418; called by muse, mutect2, varscan2
- ZNF264 | c.1140_1142del p.F380del | In Frame Del (DEL) | VAF 330/843 reads (39%) | catalogued as rs758510830; called by pindel, varscan2
- ZNF341 | c.1510C>T p.R504C (on ENST00000375200 / NM_001282935.1; = p.R497C on NM_032819.4) | Missense Mutation (SNP) | VAF 296/697 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373741402, COSV100678048; called by muse, mutect2, varscan2
- ZNF407 | c.6697G>A p.A2233T | Missense Mutation (SNP) | VAF 311/845 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs377200520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF462 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 639/1404 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as rs762772920, COSV52946184; called by muse, mutect2, varscan2
- ZNF513 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 162/370 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163484818, COSV52009801; called by muse, mutect2, varscan2
- ZNF764 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 24/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs917246100; called by muse, mutect2
- ZNF77 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 313/843 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs761501139; called by muse, mutect2, varscan2
- ABCA5 | c.1772T>G p.I591R | Missense Mutation (SNP) | VAF 294/677 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, varscan2
- ADAM10 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 532/738 reads (72%) | called by muse, varscan2
- ADAM19 | c.2526del p.A843Hfs*60 (on ENST00000517905; = p.A843Hfs*71 on NM_033274.5) | Frame Shift Del (DEL) | VAF 337/996 reads (34%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.298A>C p.S100R | Missense Mutation (SNP) | VAF 696/1621 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ANK2 | c.9431_9432del p.S3144* | Frame Shift Del (DEL) | VAF 370/1156 reads (32%) | called by pindel, varscan2
- ANKAR | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 443/1184 reads (37%) | called by muse, mutect2, varscan2
- APOE | c.237-1G>T p.X79_splice | Splice Site (SNP) | VAF 156/363 reads (43%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.1115G>A p.C372Y | Missense Mutation (SNP) | VAF 242/546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATP2A1 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 298/771 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- BRD7 | c.1688G>C p.R563P | Missense Mutation (SNP) | VAF 74/1745 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- CCDC172 | c.456G>C p.K152N | Missense Mutation (SNP) | VAF 238/647 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CUX2 | c.4199C>T p.A1400V | Missense Mutation (SNP) | VAF 24/802 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- CYP2D6 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 286/862 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, varscan2
- DNAH1 | c.4769C>T p.T1590I | Missense Mutation (SNP) | VAF 328/740 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOP1A | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 427/965 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DUSP8 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 573/1284 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ESCO1 | c.55dup p.S19Kfs*2 | Frame Shift Ins (INS) | VAF 484/1157 reads (42%) | called by mutect2, varscan2
- FAM205A | c.1832T>A p.I611N | Missense Mutation (SNP) | VAF 279/658 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN3 | c.588C>A p.C196* | Nonsense Mutation (SNP) | VAF 163/412 reads (40%) | called by muse, mutect2, varscan2
- FBXW11 | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 447/1050 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GPATCH8 | c.1196del p.P399Qfs*6 | Frame Shift Del (DEL) | VAF 361/1029 reads (35%) | called by mutect2, pindel, varscan2
- HDDC3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 243/580 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- IFT172 | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 258/709 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KPTN | c.1186A>G p.S396G | Missense Mutation (SNP) | VAF 164/395 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- LRRC20 | c.385_387del p.E129del (on ENST00000355790 / NM_207119.3; = p.E79del on NM_018239.4) | In Frame Del (DEL) | VAF 246/652 reads (38%) | called by pindel, varscan2
- LRRTM1 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.04); called by muse, mutect2
- MAGOHB | c.347A>C p.K116T | Missense Mutation (SNP) | VAF 392/1021 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MAML2 | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 18/686 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- MAPK14 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 601/1424 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAST1 | c.3264-5C>T | Splice Region (SNP) | VAF 81/221 reads (37%) | called by muse, mutect2, varscan2
- MFSD2B | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 131/321 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- MKLN1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 572/1353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MXI1 | c.71del p.P24Rfs*95 | Frame Shift Del (DEL) | VAF 124/314 reads (39%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 280/722 reads (39%) | called by muse, mutect2
- MYC | c.523A>G p.S175G (on ENST00000377970; = p.S190G on NM_002467.6) | Missense Mutation (SNP) | VAF 351/797 reads (44%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MYH1 | c.3348+2T>C p.X1116_splice | Splice Site (SNP) | VAF 599/1405 reads (43%) | called by muse, mutect2, varscan2
- MYT1 | c.2332del p.E778Kfs*4 | Frame Shift Del (DEL) | VAF 410/1136 reads (36%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 199/532 reads (37%) | called by mutect2, pindel, varscan2
- NPTN | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 37/1072 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OLIG1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 221/509 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- OR51V1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 598/1411 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 230/901 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PDGFRA | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 598/1380 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.566); called by muse, varscan2
- PIEZO1 | c.4552G>T p.G1518W | Missense Mutation (SNP) | VAF 309/693 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PLEKHA5 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 808/1863 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PNMA2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 394/988 reads (40%) | called by muse, mutect2, varscan2
- PRR14L | c.5514del p.K1838Nfs*16 | Frame Shift Del (DEL) | VAF 396/1110 reads (36%) | called by mutect2, pindel, varscan2
- PTPN21 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 212/566 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RBM19 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 319/732 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, varscan2
- SETD2 | c.843del p.E282Kfs*19 | Frame Shift Del (DEL) | VAF 690/1994 reads (35%) | called by mutect2, pindel, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 252/806 reads (31%) | called by mutect2, pindel, varscan2
- SHANK3 | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SRRT | c.1147_1149del p.K383del | In Frame Del (DEL) | VAF 200/625 reads (32%) | called by mutect2, pindel, varscan2
- STING1 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 230/566 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SV2B | c.554dup p.N185Kfs*41 | Frame Shift Ins (INS) | VAF 370/1002 reads (37%) | called by mutect2, pindel, varscan2
- SYVN1 | c.1161del p.M388Wfs*97 (on ENST00000377190 / NM_172230.3; = p.M388Wfs*96 on NM_032431.3) | Frame Shift Del (DEL) | VAF 365/1078 reads (34%) | called by mutect2, pindel, varscan2
- TEKT3 | c.663+1G>C p.X221_splice | Splice Site (SNP) | VAF 490/1131 reads (43%) | called by muse, mutect2, varscan2
- TMEM151B | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 233/446 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMEM191B | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); called by mutect2, varscan2
- TMEM191C | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 173/395 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMX3 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 46/1197 reads (4%) | called by muse, mutect2
- TOPBP1 | c.3798del p.K1266Nfs*10 | Frame Shift Del (DEL) | VAF 254/747 reads (34%) | called by mutect2, pindel, varscan2
- TTN | c.83087-1G>A p.X27696_splice (on ENST00000591111; = p.X20272_splice on NM_003319.4) | Splice Site (SNP) | VAF 72/1637 reads (4%) | called by muse, mutect2
- ZBTB10 | c.2350A>G p.K784E (on ENST00000430430; = p.K760E on NM_023929.4) | Missense Mutation (SNP) | VAF 410/969 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, varscan2
- ZER1 | c.123_125del p.F41del | In Frame Del (DEL) | VAF 392/968 reads (40%) | called by pindel, varscan2
- ZNF140 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 432/1182 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- A2ML1 | c.3648G>A p.A1216= | Silent (SNP) | VAF 388/923 reads (42%) | catalogued as rs376574474; called by muse, mutect2, varscan2
- ABCF3 | c.2049C>T p.G683= | Silent (SNP) | VAF 494/1147 reads (43%) | catalogued as rs376951098; called by muse, mutect2, varscan2
- AGRN | c.1005G>A p.P335= | Silent (SNP) | VAF 182/459 reads (40%) | called by muse, mutect2, varscan2
- ALS2 | c.4641G>A p.T1547= | Silent (SNP) | VAF 742/1829 reads (41%) | catalogued as rs759206593; ClinVar: likely benign; called by muse, mutect2, varscan2
- APBA1 | c.630C>T p.R210= | Silent (SNP) | VAF 162/425 reads (38%) | catalogued as rs1207615179, COSV99595624, COSV99597018; called by muse, mutect2, varscan2
- ARFGEF3 | c.1278C>T p.A426= | Silent (SNP) | VAF 653/1533 reads (43%) | catalogued as rs765048827; called by muse, mutect2, varscan2
- ARHGAP39 | c.2295C>T p.H765= | Silent (SNP) | VAF 216/465 reads (46%) | catalogued as rs541240053, COSV52769680; called by muse, mutect2, varscan2
- ARMC6 | c.1029C>T p.L343= (on ENST00000392336; = p.L318= on NM_033415.4) | Silent (SNP) | VAF 373/837 reads (45%) | catalogued as rs200075145, COSV99523177; called by muse, mutect2, varscan2
- ASTN1 | c.720C>T p.D240= | Silent (SNP) | VAF 380/819 reads (46%) | catalogued as rs757643505, COSV99921742; called by muse, mutect2, varscan2
- ATP2B3 | c.3207C>T p.A1069= | Silent (SNP) | VAF 359/407 reads (88%) | catalogued as rs1557017601, COSV99685387; called by muse, mutect2, varscan2
- AXIN1 | c.2130G>A p.A710= | Silent (SNP) | VAF 432/1006 reads (43%) | catalogued as rs749294095; called by muse, mutect2, varscan2
- BICRAL | c.1185C>T p.H395= | Silent (SNP) | VAF 213/478 reads (45%) | catalogued as rs368677077; called by muse, mutect2, varscan2
- C4BPA | c.378T>C p.I126= | Silent (SNP) | VAF 334/850 reads (39%) | called by muse, varscan2
- C9orf78 | c.624C>T p.S208= | Silent (SNP) | VAF 381/912 reads (42%) | catalogued as rs779029380, COSV65217512; called by muse, mutect2, varscan2
- CACNG3 | c.414G>A p.A138= | Silent (SNP) | VAF 38/1184 reads (3%) | catalogued as rs1430773509, COSV50067718; called by muse, mutect2
- CBL | c.825C>T p.D275= | Silent (SNP) | VAF 696/1749 reads (40%) | catalogued as rs751768529, COSV50635379; called by muse, mutect2, varscan2
- CC2D1A | c.2556G>A p.A852= | Silent (SNP) | VAF 250/539 reads (46%) | catalogued as rs779247588, COSV99583045; called by muse, mutect2, varscan2
- CDHR3 | c.1632C>T p.N544= | Silent (SNP) | VAF 356/860 reads (41%) | catalogued as rs753984467; called by muse, mutect2, varscan2
- CFLAR | c.771C>T p.I257= | Silent (SNP) | VAF 400/1355 reads (30%) | catalogued as rs774649089, COSV58579398; called by muse, mutect2, varscan2
- CHD6 | c.3219C>T p.S1073= | Silent (SNP) | VAF 479/1133 reads (42%) | catalogued as rs375979334, COSV58562917; called by muse, mutect2, varscan2
- CLDN18 | c.30G>A p.A10= | Silent (SNP) | VAF 334/757 reads (44%) | catalogued as rs1246377862, COSV51737086; called by muse, mutect2, varscan2
- CSMD1 | c.3093C>T p.Y1031= (on ENST00000520002; = p.Y1030= on NM_033225.6) | Silent (SNP) | VAF 439/1072 reads (41%) | catalogued as rs367552614; called by muse, mutect2, varscan2
- DNAH11 | c.7512A>G p.K2504= | Silent (SNP) | VAF 741/1766 reads (42%) | called by muse, mutect2, varscan2
- DNAH2 | c.3261C>T p.N1087= | Silent (SNP) | VAF 436/973 reads (45%) | catalogued as rs751097301; called by muse, mutect2, varscan2
- DNAH3 | c.11097C>T p.N3699= | Silent (SNP) | VAF 514/1299 reads (40%) | catalogued as rs761281498; called by muse, mutect2, varscan2
- DOCK5 | c.5556T>C p.P1852= | Silent (SNP) | VAF 40/900 reads (4%) | called by muse, mutect2
- DOK7 | c.597C>T p.I199= | Silent (SNP) | VAF 327/778 reads (42%) | catalogued as rs771302576; called by muse, mutect2, varscan2
- DOT1L | c.906G>A p.S302= | Silent (SNP) | VAF 288/656 reads (44%) | catalogued as rs754492029, COSV67110030; called by muse, varscan2
- DPP9 | c.96C>T p.D32= (on ENST00000598800; = p.D61= on NM_139159.5) | Silent (SNP) | VAF 190/426 reads (45%) | catalogued as rs753719156, COSV53590394, COSV53593017; called by muse, mutect2, varscan2
- DSCAM | c.2349G>A p.T783= | Silent (SNP) | VAF 418/1010 reads (41%) | catalogued as rs775026981; called by muse, mutect2, varscan2
- DYNC2H1 | c.1026G>A p.E342= | Silent (SNP) | VAF 203/996 reads (20%) | called by muse, mutect2, varscan2
- EEF2 | c.1371C>T p.Y457= | Silent (SNP) | VAF 313/817 reads (38%) | catalogued as rs764952218, COSV100500835, COSV100500896, COSV58580632; called by muse, mutect2, varscan2
- EMX2 | c.684G>A p.T228= | Silent (SNP) | VAF 607/1392 reads (44%) | catalogued as rs781687437, COSV71294487; called by muse, mutect2, varscan2
- EP400 | c.5505G>A p.P1835= | Silent (SNP) | VAF 317/804 reads (39%) | catalogued as rs1360115718, COSV100200254; called by muse, mutect2, varscan2
- EXTL3 | c.591C>T p.Y197= | Silent (SNP) | VAF 457/1135 reads (40%) | catalogued as rs112013792; ClinVar: likely benign; called by muse, mutect2, varscan2
- EYS | c.5901C>T p.N1967= | Silent (SNP) | VAF 467/1209 reads (39%) | catalogued as rs1024722910; called by muse, mutect2, varscan2
- FAT3 | c.9498C>T p.V3166= | Silent (SNP) | VAF 563/1257 reads (45%) | catalogued as rs141561501; called by muse, mutect2, varscan2
- FCGR2C | c.360C>T p.S120= | Silent (SNP) | VAF 365/1619 reads (23%) | catalogued as rs776624186; called by muse, mutect2, varscan2
- FGD5 | c.276C>T p.P92= | Silent (SNP) | VAF 392/923 reads (42%) | catalogued as rs753882907; called by muse, mutect2, varscan2
- FLVCR1 | c.9G>A p.R3= | Silent (SNP) | VAF 217/503 reads (43%) | called by muse, mutect2, varscan2
- FRAS1 | c.2580C>T p.C860= | Silent (SNP) | VAF 329/896 reads (37%) | called by muse, mutect2, varscan2
- FRMPD3 | c.1740C>T p.N580= | Silent (SNP) | VAF 325/366 reads (89%) | catalogued as rs766326949; called by muse, mutect2, varscan2
- GAL3ST3 | c.576C>T p.R192= | Silent (SNP) | VAF 245/594 reads (41%) | catalogued as rs758467706, COSV61749709; called by muse, mutect2, varscan2
- GAREM2 | c.981G>A p.P327= | Silent (SNP) | VAF 163/377 reads (43%) | catalogued as rs1443134661; called by muse, mutect2, varscan2
- GPR78 | c.558G>A p.A186= | Silent (SNP) | VAF 138/294 reads (47%) | called by muse, mutect2, varscan2
- HELZ2 | c.4464C>T p.A1488= (on ENST00000467148 / NM_001037335.2; = p.A919= on NM_033405.3) | Silent (SNP) | VAF 261/612 reads (43%) | catalogued as rs750691354; called by muse, mutect2
- IQGAP1 | c.1731G>A p.Q577= | Silent (SNP) | VAF 530/1404 reads (38%) | catalogued as rs1323871054; called by muse, mutect2, varscan2
- IQSEC3 | c.951C>T p.R317= (on ENST00000538872 / NM_001170738.2; = p.R14= on NM_015232.1) | Silent (SNP) | VAF 358/804 reads (45%) | catalogued as rs1555087058, COSV58284174; called by muse, mutect2, varscan2
- ITPRIP | c.312G>A p.R104= | Silent (SNP) | VAF 168/410 reads (41%) | called by muse, mutect2, varscan2
- KCNG1 | c.309C>T p.N103= | Silent (SNP) | VAF 280/590 reads (47%) | catalogued as COSV65368714; called by muse, mutect2, varscan2
- KHNYN | c.1647G>A p.A549= | Silent (SNP) | VAF 456/1068 reads (43%) | catalogued as rs370436185, COSV52159981; called by muse, mutect2, varscan2
- KIAA0586 | c.240C>T p.D80= (on ENST00000619416 / NM_001244190.2; = p.D95= on NM_014749.5) | Silent (SNP) | VAF 268/745 reads (36%) | catalogued as rs527601211; called by muse, mutect2, varscan2
- KIF7 | c.1062G>A p.T354= | Silent (SNP) | VAF 203/427 reads (48%) | catalogued as rs1284339153; called by muse, mutect2, varscan2
- KLHL12 | c.1467C>T p.S489= | Silent (SNP) | VAF 363/810 reads (45%) | catalogued as rs780577037; called by muse, mutect2, varscan2
- LGALS7B | c.279G>A p.A93= | Silent (SNP) | VAF 203/806 reads (25%) | called by muse, mutect2, varscan2
- MADD | c.4275A>G p.G1425= | Silent (SNP) | VAF 345/876 reads (39%) | called by muse, mutect2, varscan2
- MALRD1 | c.1857G>A p.S619= | Silent (SNP) | VAF 430/1156 reads (37%) | catalogued as rs548955209; called by muse, mutect2, varscan2
- MED25 | c.801C>T p.P267= | Silent (SNP) | VAF 461/1023 reads (45%) | catalogued as rs779737748; called by muse, mutect2, varscan2
- MEF2B | c.306G>A p.P102= | Silent (SNP) | VAF 332/861 reads (39%) | catalogued as rs772732125, COSV50773057; called by muse, mutect2, varscan2
- MID2 | c.402C>T p.S134= | Silent (SNP) | VAF 335/376 reads (89%) | catalogued as rs761567068, COSV99465885; called by muse, mutect2, varscan2
- MMP11 | c.603C>T p.I201= | Silent (SNP) | VAF 42/912 reads (5%) | catalogued as rs1355313081, COSV53155397; called by muse, mutect2
- MMP16 | c.1428A>G p.P476= | Silent (SNP) | VAF 477/1268 reads (38%) | called by muse, mutect2, varscan2
- MMP17 | c.432G>A p.T144= | Silent (SNP) | VAF 126/296 reads (43%) | catalogued as rs777423029; called by muse, mutect2, varscan2
- MRC1 | c.2646C>T p.Y882= | Silent (SNP) | VAF 507/1225 reads (41%) | catalogued as rs1158293889; called by muse, mutect2, varscan2
- NCAN | c.1056C>T p.D352= | Silent (SNP) | VAF 202/500 reads (40%) | catalogued as rs775283439; called by muse, mutect2, varscan2
- NKD2 | c.1086G>A p.P362= | Silent (SNP) | VAF 161/343 reads (47%) | catalogued as rs567751276; called by muse, mutect2, varscan2
- NLRP3 | c.1485G>A p.A495= | Silent (SNP) | VAF 405/862 reads (47%) | catalogued as rs373973057; called by muse, mutect2, varscan2
- OR8B2 | c.480C>T p.T160= | Silent (SNP) | VAF 258/1094 reads (24%) | catalogued as rs770274036; called by muse, mutect2
- PAK5 | c.345C>T p.H115= | Silent (SNP) | VAF 445/1030 reads (43%) | catalogued as rs780125410, COSV62027678; called by muse, mutect2, varscan2
- PAQR7 | c.966G>A p.T322= | Silent (SNP) | VAF 546/1323 reads (41%) | catalogued as rs751929346, COSV65351617; called by muse, mutect2, varscan2
- PCDHGA5 | c.1779G>A p.A593= | Silent (SNP) | VAF 54/884 reads (6%) | catalogued as rs758409280, COSV54002020; called by muse, mutect2
- PLEC | c.2337C>T p.F779= (on ENST00000322810 / NM_201380.4; = p.F669= on NM_000445.5) | Silent (SNP) | VAF 310/799 reads (39%) | catalogued as rs1432586590, COSV59638523; called by muse, mutect2, varscan2
- PLEKHM3 | c.1863G>A p.A621= | Silent (SNP) | VAF 258/637 reads (41%) | catalogued as rs1234134561; called by muse, mutect2, varscan2
- PLK5 | c.789C>T p.H263= | Silent (SNP) | VAF 383/849 reads (45%) | catalogued as rs766184335; called by muse, mutect2, varscan2
- PLXNA4 | c.4668A>G p.R1556= | Silent (SNP) | VAF 226/620 reads (36%) | called by muse, mutect2, varscan2
- PMS2 | c.2148C>T p.T716= | Silent (SNP) | VAF 189/660 reads (29%) | catalogued as rs748404138, COSV56221036; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR12 | c.2316G>A p.A772= (on ENST00000615927; = p.A1593= on NM_020719.3) | Silent (SNP) | VAF 310/676 reads (46%) | catalogued as rs929591389; called by muse, mutect2, varscan2
- PRRC2B | c.4152C>T p.S1384= | Silent (SNP) | VAF 370/896 reads (41%) | catalogued as rs369787362; called by muse, mutect2, varscan2
- PSEN2 | c.165C>T p.D55= | Silent (SNP) | VAF 169/446 reads (38%) | catalogued as rs139332886; called by muse, mutect2, varscan2
- PTK2B | c.771C>T p.F257= | Silent (SNP) | VAF 477/1091 reads (44%) | catalogued as rs780868637; called by muse, mutect2, varscan2
- PTPA | c.297C>T p.R99= | Silent (SNP) | VAF 200/548 reads (36%) | catalogued as rs140799844; called by muse, mutect2, varscan2
- PTPRC | c.1599G>A p.S533= | Silent (SNP) | VAF 550/1352 reads (41%) | catalogued as rs372045826; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1848G>A p.P616= | Silent (SNP) | VAF 497/1201 reads (41%) | catalogued as rs368626850, COSV99920673, COSV99921226; called by muse, mutect2, varscan2
- RAB40B | c.498G>A p.S166= | Silent (SNP) | VAF 214/481 reads (44%) | catalogued as rs374410879; called by muse, mutect2, varscan2
- RAI1 | c.3663G>A p.A1221= | Silent (SNP) | VAF 250/628 reads (40%) | catalogued as rs377730234; called by muse, mutect2, varscan2
- RIN1 | c.501C>T p.H167= | Silent (SNP) | VAF 393/889 reads (44%) | catalogued as rs143847360; called by muse, mutect2, varscan2
- RNF213 | c.11904C>T p.H3968= | Silent (SNP) | VAF 575/1380 reads (42%) | catalogued as rs368985577; called by muse, mutect2, varscan2
- RUSC2 | c.729C>T p.S243= | Silent (SNP) | VAF 176/456 reads (39%) | catalogued as rs772778369; called by muse, mutect2, varscan2
- SLC25A2 | c.165C>T p.Y55= | Silent (SNP) | VAF 258/665 reads (39%) | catalogued as rs782639795, COSV53402947; called by muse, mutect2, varscan2
- SLC34A2 | c.2055C>T p.T685= | Silent (SNP) | VAF 29/983 reads (3%) | catalogued as rs903673840; called by muse, mutect2
- SPRED2 | c.624G>A p.P208= | Silent (SNP) | VAF 410/994 reads (41%) | catalogued as COSV100710035; called by muse, mutect2, varscan2
- SPTBN2 | c.5586C>T p.D1862= | Silent (SNP) | VAF 131/342 reads (38%) | catalogued as rs138346945; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTLC2 | c.123C>A p.A41= | Silent (SNP) | VAF 160/392 reads (41%) | called by mutect2, varscan2
- SRCIN1 | c.1143C>T p.H381= (on ENST00000621492; = p.H347= on NM_025248.3) | Silent (SNP) | VAF 225/528 reads (43%) | catalogued as rs370389781; called by muse, mutect2, varscan2
- SRPK1 | c.1611G>A p.T537= | Silent (SNP) | VAF 313/837 reads (37%) | catalogued as rs749464029, COSV60412317; called by muse, mutect2, varscan2
- TBC1D10B | c.1509G>A p.P503= | Silent (SNP) | VAF 345/813 reads (42%) | catalogued as rs373878962; called by muse, mutect2, varscan2
- TMCC2 | c.1158C>T p.D386= | Silent (SNP) | VAF 257/632 reads (41%) | catalogued as rs766744260; called by muse, mutect2, varscan2
- TMEM39B | c.1101C>T p.N367= | Silent (SNP) | VAF 265/622 reads (43%) | catalogued as rs139160821, COSV100297803; called by muse, mutect2, varscan2
- TRIO | c.5241C>T p.P1747= | Silent (SNP) | VAF 383/823 reads (47%) | catalogued as rs926925229; called by muse, mutect2, varscan2
- TTLL12 | c.1653C>T p.I551= | Silent (SNP) | VAF 19/716 reads (3%) | called by muse, mutect2
- TULP1 | c.75G>A p.P25= | Silent (SNP) | VAF 340/799 reads (43%) | called by muse, mutect2, varscan2
- TUSC3 | c.627G>A p.S209= | Silent (SNP) | VAF 469/1172 reads (40%) | catalogued as rs201729856; called by muse, mutect2, varscan2
- USP34 | c.4950C>T p.S1650= | Silent (SNP) | VAF 719/1710 reads (42%) | catalogued as rs748706549; called by muse, mutect2, varscan2
- USP6 | c.2757G>A p.A919= | Silent (SNP) | VAF 530/1342 reads (39%) | catalogued as rs1451921478; called by muse, mutect2, varscan2
- VIL1 | c.1020C>T p.A340= | Silent (SNP) | VAF 282/740 reads (38%) | catalogued as rs778555180, COSV50294061; called by muse, mutect2, varscan2
- VPS37C | c.525A>G p.P175= | Silent (SNP) | VAF 28/565 reads (5%) | called by muse, mutect2
- VWA5B1 | c.309C>T p.D103= | Silent (SNP) | VAF 430/1011 reads (43%) | catalogued as rs992523891, COSV57057261; called by muse, mutect2, varscan2
- VWA5B2 | c.2085C>T p.P695= | Silent (SNP) | VAF 189/358 reads (53%) | catalogued as rs186251501; called by muse, mutect2, varscan2
- WARS2 | c.360C>T p.H120= | Silent (SNP) | VAF 477/1157 reads (41%) | catalogued as rs1307008212; called by muse, mutect2, varscan2
- ZIC2 | c.882C>T p.G294= | Silent (SNP) | VAF 356/827 reads (43%) | called by muse, varscan2
- ZNF324 | c.1638C>T p.A546= | Silent (SNP) | VAF 166/407 reads (41%) | catalogued as rs763442788; called by muse, mutect2, varscan2
- ZNF516 | c.1107C>T p.A369= | Silent (SNP) | VAF 171/384 reads (45%) | catalogued as rs369604123; called by muse, mutect2, varscan2
- ZNF799 | c.1317T>C p.H439= | Silent (SNP) | VAF 275/701 reads (39%) | called by muse, mutect2, varscan2
- ZSWIM1 | c.708C>T p.N236= | Silent (SNP) | VAF 115/1065 reads (11%) | catalogued as rs766960027; called by muse, mutect2, varscan2
- ZXDC | c.1920G>A p.P640= | Silent (SNP) | VAF 421/1044 reads (40%) | catalogued as rs569926360, COSV100306499; called by muse, mutect2, varscan2
- ACO2 | c.835+20G>A | Intron (SNP) | VAF 201/543 reads (37%) | catalogued as rs199847369; called by muse, mutect2, varscan2
- ADAM12 | c.1618+11G>A | Intron (SNP) | VAF 326/691 reads (47%) | catalogued as rs200391548; called by muse, mutect2, varscan2
- APP | c.1964-26C>T | Intron (SNP) | VAF 214/400 reads (54%) | called by muse, mutect2, varscan2
- ASAP2 | c.1024-13dup | Intron (INS) | VAF 445/1232 reads (36%) | catalogued as rs1205458695; called by mutect2, pindel, varscan2
- ASIC1 | c.559-3121G>A | Intron (SNP) | VAF 219/494 reads (44%) | catalogued as rs951404187; called by muse, mutect2, varscan2
- ATRX | c.*57del | 3'UTR (DEL) | VAF 111/124 reads (90%) | catalogued as rs1263405963; called by mutect2, varscan2
- BAIAP2L1 | c.*23G>A | 3'UTR (SNP) | VAF 180/443 reads (41%) | catalogued as rs1002092709; called by muse, mutect2
- C2CD5 | c.1902+92del | Intron (DEL) | VAF 60/144 reads (42%) | catalogued as rs761989178; called by mutect2, varscan2
- CCDC17 | c.1389-76G>A | Intron (SNP) | VAF 122/292 reads (42%) | catalogued as rs1297419487; called by muse, mutect2, varscan2
- CD9 | c.447+40C>T | Intron (SNP) | VAF 180/394 reads (46%) | catalogued as rs747977742; called by muse, mutect2, varscan2
- CLASP2 | c.2351-92del | Intron (DEL) | VAF 80/201 reads (40%) | called by mutect2, varscan2
- COASY | c.-202C>G | 5'UTR (SNP) | VAF 156/331 reads (47%) | called by muse, mutect2, varscan2
- CS | c.588+73del | Intron (DEL) | VAF 125/349 reads (36%) | called by mutect2, pindel, varscan2
- CSMD2 | c.*2360del | 3'UTR (DEL) | VAF 62/154 reads (40%) | catalogued as rs1164658776; called by mutect2, varscan2
- CXXC1 | c.4-55del | Intron (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- DACH2 | c.1751-4del | Intron (DEL) | VAF 84/468 reads (18%) | catalogued as rs753870016; called by mutect2, varscan2
- DNAL4 | c.153+21G>A | Intron (SNP) | VAF 162/358 reads (45%) | catalogued as rs748737615; called by muse, varscan2
- DPPA4 | c.179-74del | Intron (DEL) | VAF 56/116 reads (48%) | catalogued as rs571043981; called by mutect2, varscan2
- DSC2 | c.*53del | 3'UTR (DEL) | VAF 188/380 reads (49%) | catalogued as rs1377866477; called by mutect2, varscan2
- DYNC1H1 | c.7473+39C>T | Intron (SNP) | VAF 216/458 reads (47%) | catalogued as rs940641274; called by muse, mutect2, varscan2
- EDRF1 | c.3124-89A>G | Intron (SNP) | VAF 67/165 reads (41%) | called by muse, mutect2, varscan2
- ELP2 | c.289-42del | Intron (DEL) | VAF 114/261 reads (44%) | catalogued as rs761640327; called by mutect2, varscan2
- EYA1 | c.-45_-43del | 5'UTR (DEL) | VAF 193/410 reads (47%) | called by pindel, varscan2
- FAAP20 | chr1:2184898 del C | 3'Flank (DEL) | VAF 114/305 reads (37%) | catalogued as rs767095736, COSV61598635; called by mutect2, pindel, varscan2
- FOXP1 | c.975-91G>A | Intron (SNP) | VAF 128/261 reads (49%) | catalogued as rs572511609; called by muse, mutect2, varscan2
- GDF2 | c.-89C>T | 5'UTR (SNP) | VAF 20/42 reads (48%) | catalogued as rs1011955070; called by muse, mutect2
- GFOD1 | c.253+16155_253+16156del | Intron (DEL) | VAF 369/1167 reads (32%) | called by pindel, varscan2
- H2BC18 | c.-33_-31del | 5'UTR (DEL) | VAF 224/556 reads (40%) | called by pindel, varscan2
- HCAR3 | c.*70G>A | 3'UTR (SNP) | VAF 70/222 reads (32%) | called by muse, mutect2
- HNRNPA2B1 | c.7-9T>C | Intron (SNP) | VAF 344/882 reads (39%) | catalogued as rs773972068, COSV61159208; ClinVar: likely benign; called by mutect2, varscan2
- IGDCC4 | c.*67G>A | 3'UTR (SNP) | VAF 93/114 reads (82%) | called by muse, mutect2, varscan2
- IKZF4 | c.-176G>A | 5'UTR (SNP) | VAF 298/732 reads (41%) | catalogued as rs1173572626; called by muse, mutect2, varscan2
- IKZF5 | c.*62dup | 3'UTR (INS) | VAF 115/313 reads (37%) | catalogued as rs1206917302; called by mutect2, pindel, varscan2
- ILF3 | c.2059+825G>A | Intron (SNP) | VAF 182/441 reads (41%) | called by muse, mutect2, varscan2
- IQCG | c.888+53C>G | Intron (SNP) | VAF 253/511 reads (50%) | called by muse, mutect2, varscan2
- KANK2 | c.1249+49del | Intron (DEL) | VAF 16/84 reads (19%) | catalogued as rs761900295; called by pindel, varscan2
- KCNJ18 | c.*32C>A | 3'UTR (SNP) | VAF 178/394 reads (45%) | called by muse, mutect2, varscan2
- KCTD4 | c.-44del | 5'UTR (DEL) | VAF 426/1158 reads (37%) | called by mutect2, pindel, varscan2
- LIMS2 | c.238+56G>A | Intron (SNP) | VAF 201/433 reads (46%) | catalogued as rs746037222; called by muse, mutect2, varscan2
- LSMEM1 | c.*51C>A | 3'UTR (SNP) | VAF 159/369 reads (43%) | catalogued as COSV100456293; called by muse, mutect2, varscan2
- LTO1 | c.157-99C>T | Intron (SNP) | VAF 30/62 reads (48%) | catalogued as rs1433763994; called by muse, mutect2, varscan2
- MARK3 | c.*88C>T | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- MPV17 | c.*94C>T | 3'UTR (SNP) | VAF 70/154 reads (45%) | catalogued as rs942966851; called by muse, mutect2, varscan2
- MRNIP | c.216-31dup | Intron (INS) | VAF 186/563 reads (33%) | called by mutect2, pindel, varscan2
- MTG1 | c.511+44C>T | Intron (SNP) | VAF 112/160 reads (70%) | catalogued as rs368401199; called by muse, mutect2, varscan2
- NDUFA13 | c.316-87C>T | Intron (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- NDUFB1 | c.-5-41_-5-40insCAA | Intron (INS) | VAF 92/286 reads (32%) | catalogued as rs761541920; called by mutect2, pindel, varscan2
- NEO1 | c.-91C>G | 5'UTR (SNP) | VAF 51/58 reads (88%) | called by muse, varscan2
- NRG1 | c.502+31109G>A | Intron (SNP) | VAF 466/1056 reads (44%) | catalogued as rs770213928, COSV55155772; called by muse, mutect2, varscan2
- OSBPL2 | c.782+66G>A | Intron (SNP) | VAF 44/121 reads (36%) | catalogued as rs1322104574; called by muse, mutect2, varscan2
- PACS2 | c.1989-89C>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as rs587742306; called by muse, mutect2, varscan2
- PLCH2 | c.2959+329C>T | Intron (SNP) | VAF 122/252 reads (48%) | catalogued as rs1187817562; called by muse, mutect2, varscan2
- PLD2 | c.2010-8del | Intron (DEL) | VAF 91/239 reads (38%) | called by mutect2, pindel, varscan2
- PLEKHA8 | c.638+41del | Intron (DEL) | VAF 167/430 reads (39%) | catalogued as rs752914669; called by mutect2, varscan2
- PLSCR1 | c.739-9del | Intron (DEL) | VAF 162/389 reads (42%) | catalogued as rs753151379; called by mutect2, varscan2
- PMM2 | c.*1C>T | 3'UTR (SNP) | VAF 229/531 reads (43%) | catalogued as rs370860106; called by muse, mutect2, varscan2
- PNKP | c.1298+19C>T | Intron (SNP) | VAF 148/376 reads (39%) | catalogued as rs541129252; ClinVar: benign; called by muse, varscan2
- PRKDC | c.*90T>C | 3'UTR (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- PRMT8 | c.418-35del | Intron (DEL) | VAF 274/701 reads (39%) | called by mutect2, varscan2
- PSME4 | c.*4+43A>G | Intron (SNP) | VAF 327/748 reads (44%) | called by muse, mutect2, varscan2
- PTPRF | c.*80G>A | 3'UTR (SNP) | VAF 72/170 reads (42%) | catalogued as rs993667231; called by muse, mutect2
- PVALB | c.*64G>A | 3'UTR (SNP) | VAF 20/480 reads (4%) | catalogued as rs929325033; called by muse, mutect2
- PYCARD | c.-22A>C | 5'UTR (SNP) | VAF 138/367 reads (38%) | called by muse, mutect2, varscan2
- RGS12 | c.4114+36G>A | Intron (SNP) | VAF 218/534 reads (41%) | catalogued as rs751752373, COSV100122557; called by muse, mutect2, varscan2
- RRP36 | c.*80G>A | 3'UTR (SNP) | VAF 120/259 reads (46%) | catalogued as rs746012779; called by muse, mutect2, varscan2
- SEMA3B | c.1491+54C>T | Intron (SNP) | VAF 171/414 reads (41%) | called by muse, mutect2, varscan2
- SEMA4C | c.1444-19C>T | Intron (SNP) | VAF 134/269 reads (50%) | catalogued as rs751772565; called by muse, mutect2, varscan2
- SHFL | c.235-30del | Intron (DEL) | VAF 51/132 reads (39%) | catalogued as rs761104658; called by mutect2, pindel, varscan2
- SLC25A34 | c.-96G>A | 5'UTR (SNP) | VAF 37/73 reads (51%) | catalogued as rs1250959604; called by muse, mutect2, varscan2
- STOM | c.*14G>A | 3'UTR (SNP) | VAF 370/915 reads (40%) | catalogued as rs761374818; called by muse, mutect2, varscan2
- STXBP4 | c.*47C>T | 3'UTR (SNP) | VAF 459/1083 reads (42%) | catalogued as rs375419172; called by muse, mutect2, varscan2
- TBL3 | c.94-39dup | Intron (INS) | VAF 181/501 reads (36%) | catalogued as rs759212096; called by mutect2, pindel, varscan2
- TEX37 | c.*9A>G | 3'UTR (SNP) | VAF 13/491 reads (3%) | called by muse, mutect2
- TINAGL1 | c.1217+9C>T | Intron (SNP) | VAF 179/422 reads (42%) | catalogued as rs746577046, COSV54700127; called by muse, mutect2, varscan2
- TM7SF2 | c.500-14C>T | Intron (SNP) | VAF 332/793 reads (42%) | called by muse, mutect2, varscan2
- TMEM181 | c.*60C>A | 3'UTR (SNP) | VAF 117/262 reads (45%) | called by muse, mutect2, varscan2
- TOB1 | chr17:50862921 del A | 3'Flank (DEL) | VAF 128/274 reads (47%) | catalogued as rs546261730; called by mutect2, varscan2
- TRIM29 | c.1628-36G>A | Intron (SNP) | VAF 94/214 reads (44%) | catalogued as rs1216410735; called by muse, mutect2, varscan2
- TRIQK | c.148-9del | Intron (DEL) | VAF 302/702 reads (43%) | catalogued as rs760147438; called by mutect2, varscan2
- TSEN34 | c.*385del | 3'UTR (DEL) | VAF 101/314 reads (32%) | catalogued as rs1156850349; ClinVar: benign; called by mutect2, pindel, varscan2
- WDR90 | c.1438-41G>A | Intron (SNP) | VAF 71/156 reads (46%) | catalogued as rs1001378990; called by muse, mutect2, varscan2
- WWP1 | c.2596+33G>A | Intron (SNP) | VAF 247/509 reads (49%) | catalogued as rs771452429; called by muse, mutect2, varscan2
- XPA | c.*87del | 3'UTR (DEL) | VAF 94/202 reads (47%) | catalogued as rs750807332; called by mutect2, varscan2
- ZFYVE21 | c.526+49C>T | Intron (SNP) | VAF 139/334 reads (42%) | catalogued as rs766979607; called by muse, mutect2, varscan2
